MMRF case MMRF_2727 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4e70abb5-296f-40ea-9047-4b0abf1eeb2b

Demographics
Sex at birth: male; Age at index: 48 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 48.5 years (17,712 days); ISS stage: II; Days to last known disease status: 166 days; Days to last follow up: 166 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -13, day 166.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Serum Free Immunoglobulin Light Chain, Kappa 32.6 mg/dL.
- M Protein 7.3 g/dL.
- Beta 2 Microglobulin 4.04 µg/mL.
- Serum Free Immunoglobulin Light Chain, Lambda 0.87 mg/dL.
- Albumin 31.6 g/L.
- Absolute Neutrophil 2.63 ×10⁹/L.
- Hemoglobin 6.01 mmol/L.
- Platelets 179 ×10⁹/L.
- Calcium 3.13 mmol/L.

Other clinical attributes
- Day -13: Weight: 66 kg; Height: 170 cm.

Biospecimens (2 samples)
- Sample MMRF_2727_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_2727_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
